Somatic mutation profile of tumor specimen BA2972D (aliquot aq-BA2972D) from BEATAML1.0 case 2111, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with mutated CEBPA; Tissue or organ of origin: Bone marrow; Age at diagnosis: 40.1 years (14,632 days).
Specimen BA2972D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cf083a35-31a5-47ff-8d81-3523d7afe2cf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2869D (Solid Tissue Normal), aliquot aq-BA2869D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/86bc5f25-9b06-43b4-8e85-9f23681ed9b5

The open-access MAF lists 11 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 8, Nonsense Mutation 1, Silent 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GATA2 | c.959G>A p.G320D | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62003029, COSV62003510, COSV62004917; called by muse, varscan2
- CEBPA | c.81_82insGGCG p.S28Gfs*81 | Frame Shift Ins (INS) | VAF 6/18 reads (33%) | called by mutect2, varscan2
- GLS | c.1734C>A p.D578E | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); called by muse, mutect2
- HSPA12A | c.943G>C p.D315H | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- HSPG2 | c.6142G>T p.A2048S | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.024); called by muse, mutect2
- LOXHD1 | c.2198G>T p.R733L | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.638); called by muse, mutect2
- NPR3 | c.195C>A p.Y65* | Nonsense Mutation (SNP) | VAF 3/24 reads (13%) | called by muse, mutect2
- SLC41A2 | c.286G>T p.A96S | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.97); PolyPhen benign (0); called by muse, mutect2
- TTN | c.73638G>T p.E24546D (on ENST00000591111; = p.E17122D on NM_003319.4) | Missense Mutation (SNP) | VAF 3/21 reads (14%) | PolyPhen benign (0.026); called by muse, mutect2
- YIF1A | c.791C>A p.P264H | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, varscan2
- PLXNC1 | c.888C>T p.S296= | Silent (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2
